Somatic mutation profile of tumor specimen TCGA-L5-A4OX-01A (aliquot TCGA-L5-A4OX-01A-21D-A28B-09) from TCGA case TCGA-L5-A4OX, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 60.3 years (22,015 days).
Specimen TCGA-L5-A4OX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f7ec37e-813b-4c96-a667-0a8f34f86d80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OX-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OX-11A-13D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1092d0d-6660-4a31-b5eb-d5ae6557fa0d

The open-access MAF lists 140 somatic variants for this specimen: 100 protein-altering or splice-affecting, 37 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 37, Nonsense Mutation 5, Frame Shift Ins 3, Frame Shift Del 3, Intron 2, In Frame Del 2, Splice Region 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.2537G>T p.S846I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.32); PolyPhen possibly damaging (0.478); catalogued as COSV57248451; called by muse, mutect2, varscan2
- PREX2 | c.148T>G p.L50V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV55750189, COSV55751655, COSV99910567; called by muse, mutect2
- AC018630.4 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 51/140 reads (36%) | catalogued as rs200314617, COSV57392333; called by muse, mutect2, varscan2
- ACSS3 | c.497A>C p.K166T | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.055); catalogued as COSV99698567; called by muse, mutect2, varscan2
- AGO2 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 64/107 reads (60%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201542441; called by muse, mutect2, varscan2
- AHNAK2 | c.7799C>T p.A2600V | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs376661887; called by muse, mutect2, varscan2
- ATP2B2 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs200591536, COSV59489530; called by muse, mutect2, varscan2
- BRINP1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs1453440054, COSV99775127; called by muse, mutect2, varscan2
- CDH23 | c.4844C>T p.S1615L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.759); catalogued as rs773077827; called by muse, mutect2, varscan2
- CES1 | c.866A>G p.K289R | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV62085679; called by muse, mutect2, varscan2
- CHRNA3 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.788); catalogued as rs751388943, COSV100468268; called by muse, mutect2, varscan2
- CNGA4 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.091); catalogued as COSV101171810; called by muse, mutect2, varscan2
- F8 | c.4057G>A p.D1353N | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868918541; called by muse, mutect2, varscan2
- FAR2 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs763416880; called by muse, mutect2, varscan2
- FAT4 | c.442A>C p.S148R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1164737344, COSV67890080, COSV67896300; called by muse, mutect2, varscan2
- FLG2 | c.1651A>G p.S551G | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66166341, COSV66166598; called by muse, mutect2, varscan2
- GAB4 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); catalogued as rs751493980; called by muse, mutect2, varscan2
- GABBR2 | c.324C>T p.C108= | Splice Region (SNP) | VAF 13/64 reads (20%) | catalogued as rs145095054; called by muse, mutect2, varscan2
- GOLGA3 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs1043198034, COSV52628169; called by muse, mutect2, varscan2
- GSG1L | c.746G>A p.R249Q (on ENST00000447459 / NM_001109763.2; = p.R94Q on NM_144675.2) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as rs767489098, COSV66580934; called by muse, mutect2, varscan2
- IL1RN | c.379C>T p.R127C (on ENST00000409930 / NM_173842.3; = p.R109C on NM_000577.5) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs148520303; called by muse, mutect2
- IQSEC3 | c.72C>G p.N24K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs2650190, COSV58280056; called by muse, mutect2
- KDM4B | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as rs993718687; called by muse, mutect2, varscan2
- MAGEB10 | c.651T>A p.C217* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | catalogued as COSV63311471; called by muse, mutect2, varscan2
- MAGEC1 | c.3184T>G p.S1062A | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV53571565; called by muse, mutect2, varscan2
- MCF2 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs766972582, COSV58483217; called by muse, mutect2, varscan2
- MEF2D | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61729462; called by muse, mutect2, varscan2
- MRC1 | c.1919C>T p.T640M | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs970799233; called by muse, mutect2, varscan2
- NPM2 | c.539dup p.L181Afs*13 | Frame Shift Ins (INS) | VAF 27/36 reads (75%) | catalogued as rs770540772; called by mutect2, varscan2
- OR10Z1 | c.267C>G p.D89E | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs770668580; called by muse, mutect2, varscan2
- OR51M1 | c.140A>G p.Y47C | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60784213; called by muse, mutect2, varscan2
- OR5B2 | c.899A>C p.K300T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as COSV56907885; called by muse, mutect2, varscan2
- PABPC4 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs141523814; called by muse, mutect2, varscan2
- RPL10L | c.560A>G p.K187R | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV53559335, COSV53559592; called by muse, mutect2, varscan2
- SDK1 | c.4426C>T p.R1476W | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs368261349; called by muse, mutect2, varscan2
- SLC25A46 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as rs139039234; called by muse, mutect2, varscan2
- SLC6A11 | c.1757A>G p.K586R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99594220; called by muse, mutect2, varscan2
- SRRM3 | c.1933C>T p.R645W | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as rs782419324; called by muse, mutect2, varscan2
- TAF1L | c.3614G>A p.R1205Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs749284231, COSV54256396; called by muse, mutect2
- TNC | c.4027G>A p.V1343I | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs145446426; called by muse, mutect2, varscan2
- USP15 | c.842G>A p.R281K (on ENST00000280377 / NM_001351159.2; = p.R252K on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.165); catalogued as COSV99739993; called by muse, mutect2, varscan2
- USP26 | c.1044dup p.K349* | Frame Shift Ins (INS) | VAF 38/50 reads (76%) | catalogued as rs772870708; called by mutect2, varscan2
- ZNF208 | c.1836A>C p.E612D | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.987); catalogued as rs553606877; called by muse, varscan2
- ZNF98 | c.367A>G p.R123G | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV63335342, COSV63340837; called by muse, mutect2, varscan2
- AASDH | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ABCC5 | c.2640G>C p.L880F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRL1 | c.1705G>A p.D569N (on ENST00000340736 / NM_001008701.3; = p.D564N on NM_014921.5) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ADGRV1 | c.2367A>C p.K789N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AHDC1 | c.2353G>T p.G785* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- AKNA | c.1479G>T p.Q493H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ARHGAP28 | c.1881A>C p.Q627H (on ENST00000383472 / NM_001366230.1; = p.Q468H on NM_001010000.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- ARID1A | c.6583dup p.L2195Pfs*30 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- ATP2A2 | c.1561A>T p.I521F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- BCL2L14 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA1E | c.3810G>C p.K1270N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHD5 | c.1045T>C p.C349R | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CLEC5A | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DENND2C | c.2161C>A p.Q721K (on ENST00000393274 / NM_001256404.2; = p.Q664K on NM_198459.4) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIAPH3 | c.1535T>C p.L512P (on ENST00000400324 / NM_001042517.2; = p.L249P on NM_030932.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- DISP3 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2
- EDC3 | c.1422C>G p.I474M | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- EGFLAM | c.52del p.L18Sfs*18 | Frame Shift Del (DEL) | VAF 18/36 reads (50%) | called by mutect2, pindel, varscan2
- FPR2 | c.985T>G p.S329A | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- FSCB | c.2007A>C p.E669D | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- GLP1R | c.1058C>A p.T353K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GYS2 | c.647C>A p.A216E | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- IGHG4 | c.8C>A p.T3N | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- JMJD1C | c.2606_2614del p.G869_H871del | In Frame Del (DEL) | VAF 23/63 reads (37%) | called by mutect2, pindel, varscan2
- JMJD7-PLA2G4B | c.1572+2T>C p.X524_splice | Splice Site (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- KRT37 | c.503G>T p.S168I | Missense Mutation (SNP) | VAF 27/435 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2
- LAMA1 | c.7127T>G p.L2376R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MCM3AP | c.1050_1055del p.E351_V352del | In Frame Del (DEL) | VAF 21/134 reads (16%) | called by mutect2, pindel, varscan2
- MYT1L | c.3043C>A p.H1015N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NME8 | c.695A>C p.K232T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR10G7 | c.532T>A p.C178S | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2M5 | c.282G>A p.M94I | Missense Mutation (SNP) | VAF 107/208 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR4C3 | c.323T>G p.V108G | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PARVG | c.906del p.K303Rfs*4 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- PGGT1B | c.571A>T p.M191L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- PLCL1 | c.879A>C p.K293N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PLXNB1 | c.1988A>T p.K663M | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PODNL1 | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLQ | c.3265A>C p.T1089P | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PRDM16 | c.1927G>T p.A643S | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAB11FIP4 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- RPLP1 | c.34T>C p.S12P | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SCN3A | c.4708A>C p.T1570P | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SEMG2 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SIAE | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- SNURF | c.190T>G p.L64V | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- SNX19 | c.1917A>C p.Q639H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SPAG16 | c.1160T>G p.L387R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TENT5D | c.440T>G p.I147S | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TP53 | c.771_778del p.E258Qfs*3 | Frame Shift Del (DEL) | VAF 46/62 reads (74%) | called by mutect2, pindel, varscan2
- TTN | c.89837A>G p.K29946R (on ENST00000591111; = p.K22522R on NM_003319.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TTN | c.40005A>C p.K13335N (on ENST00000591111; = p.K5911N on NM_003319.4) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | PolyPhen benign (0.134); called by muse, mutect2, varscan2
- TUBGCP6 | c.5359C>A p.L1787I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZKSCAN7 | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF267 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ZNF649 | c.178T>G p.L60V | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- ALKAL1 | c.147C>T p.P49= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, varscan2
- ANAPC7 | c.840G>A p.L280= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV101484770; called by muse, mutect2, varscan2
- BEND5 | c.879C>A p.I293= | Silent (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- CATSPERZ | c.198C>T p.H66= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- CD177 | c.16C>T p.L6= | Silent (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- CEACAM3 | c.486C>T p.V162= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as rs782364341, COSV55760733; called by muse, mutect2, varscan2
- CNTD1 | c.375G>T p.V125= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- CNTNAP1 | c.1731C>T p.H577= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV52855035; called by muse, mutect2, varscan2
- COG7 | c.1671G>A p.G557= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2
- COPA | c.291C>T p.R97= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs971743876; called by muse, mutect2, varscan2
- CT45A1 | c.78G>A p.S26= | Silent (SNP) | VAF 72/303 reads (24%) | called by muse, mutect2, varscan2
- DNAH5 | c.3840T>G p.S1280= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV54211882, COSV54231460; called by muse, mutect2, varscan2
- EXPH5 | c.4188T>A p.T1396= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- FAM153A | c.450A>C p.V150= | Silent (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- FAM153B | c.681A>C p.V227= (on ENST00000253490; = p.V150= on NM_001265615.1) | Silent (SNP) | VAF 49/335 reads (15%) | called by muse, mutect2, varscan2
- FBP2 | c.603C>G p.V201= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as rs959088264; called by muse, mutect2, varscan2
- ITPR1 | c.2169G>A p.G723= (on ENST00000354582; = p.G708= on NM_002222.7) | Silent (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- MDGA2 | c.2403G>A p.V801= (on ENST00000399232 / NM_001113498.2; = p.V503= on NM_182830.4) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1247380797; called by muse, mutect2, varscan2
- MITF | c.1458C>T p.V486= (on ENST00000448226 / NM_006722.3; = p.V386= on NM_000248.4) | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs748817904, COSV100096538; called by muse, mutect2, varscan2
- NKAIN4 | c.468C>T p.I156= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs946673985, COSV64785370; called by muse, mutect2, varscan2
- OR10A5 | c.637T>C p.L213= | Silent (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- OR8H3 | c.735C>T p.L245= | Silent (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- PLEC | c.11370C>T p.F3790= (on ENST00000322810 / NM_201380.4; = p.F3680= on NM_000445.5) | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs373814127; called by muse, mutect2
- RHBG | c.405C>T p.A135= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs76801898; called by muse, mutect2
- RIMS1 | c.4780A>C p.R1594= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV53462674, COSV53463828; called by muse, mutect2, varscan2
- RNFT2 | c.429C>T p.D143= | Silent (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- SI | c.4722T>G p.T1574= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs1214650677, COSV52266926, COSV52270323, COSV52288834; called by muse, mutect2, varscan2
- SLIT3 | c.2475G>A p.L825= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs780702154; called by muse, mutect2, varscan2
- SPEG | c.2133C>T p.Y711= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs371768029; called by muse, mutect2, varscan2
- SRRM2 | c.3861C>T p.S1287= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs895980241; called by muse, mutect2, varscan2
- TBX15 | c.1224T>C p.A408= (on ENST00000369429 / NM_001330677.2; = p.A302= on NM_152380.3) | Silent (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- TNC | c.669C>T p.S223= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs766404514; called by muse, mutect2, varscan2
- TSC22D2 | c.528A>G p.R176= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- TSPAN33 | c.594G>T p.V198= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- ZNF23 | c.939T>C p.C313= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs1411290635; called by muse, mutect2, varscan2
- ZNF804A | c.645T>G p.S215= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV56451180, COSV56458592; called by muse, mutect2, varscan2
- ZNHIT1 | c.129C>T p.D43= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV100522028; called by muse, mutect2, varscan2
- MAP4K4 | c.3336+20C>A | Intron (SNP) | VAF 23/124 reads (19%) | catalogued as COSV56330942; called by muse, mutect2, varscan2
- PRRX1 | c.599+3881C>T | Intron (SNP) | VAF 7/95 reads (7%) | catalogued as COSV53420271, COSV99509435; called by muse, mutect2
- SNORD115-10 | n.6G>A | RNA (SNP) | VAF 55/162 reads (34%) | catalogued as rs372092312; called by muse, mutect2, varscan2
